Somatic mutation profile of tumor specimen TCGA-AG-3584-01A (aliquot TCGA-AG-3584-01A-01D-1989-10) from TCGA case TCGA-AG-3584, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 60.8 years (22,189 days).
Specimen TCGA-AG-3584-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae7a1a92-084a-40fe-bd39-d32056b5ffbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3584-10A (Blood Derived Normal), aliquot TCGA-AG-3584-10A-01D-1989-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9ad0ec1-7144-4b15-8260-e7c60435e67d

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS8 | c.2558A>T p.Q853L | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV99960536; called by muse, mutect2
- CNGA1 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV100652169; called by muse, mutect2
- DCLK3 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 129/213 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs1389909658, COSV101373912; called by muse, mutect2, varscan2
- FBXO43 | c.1043T>C p.L348P | Missense Mutation (SNP) | VAF 218/332 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV101413824; called by muse, mutect2, varscan2
- IRX6 | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99306276; called by muse, mutect2
- JUNB | c.571G>C p.A191P | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100040119; called by muse, varscan2
- KCNH3 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.773); catalogued as rs1449511347, COSV99234901; called by muse, mutect2, varscan2
- MOGS | c.2345A>G p.K782R | Missense Mutation (SNP) | VAF 113/268 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs775094626, COSV99270364; called by muse, mutect2, varscan2
- OR2A2 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 466/1747 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV101286629, COSV68872266; called by muse, mutect2, varscan2
- PCDHA5 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 142/402 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100972176; called by muse, mutect2, varscan2
- SPEG | c.9440C>T p.A3147V | Missense Mutation (SNP) | VAF 96/532 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753034498, COSV56676120; called by muse, mutect2, varscan2
- SYMPK | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 158/397 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV99841490; called by muse, varscan2
- SYTL1 | c.1376G>A p.R459H (on ENST00000543823; = p.R447H on NM_032872.3) | Missense Mutation (SNP) | VAF 155/228 reads (68%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs760441498, COSV58872090; called by muse, mutect2, varscan2
- TRIM3 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs944397811, COSV61986296; called by muse, mutect2, varscan2
- UBP1 | c.104dup p.Y35* | Nonsense Mutation (INS) | VAF 36/72 reads (50%) | called by mutect2, pindel, varscan2
- OGFR | c.102G>A p.R34= | Silent (SNP) | VAF 36/39 reads (92%) | catalogued as COSV99283846; called by muse, mutect2, varscan2
- PCDHA2 | c.1794C>T p.D598= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs1554120090, COSV100974053, COSV65366677; called by muse, mutect2, varscan2
- PCDHA4 | c.1362G>A p.A454= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as rs782013709, COSV63538547; called by muse, mutect2, varscan2
- PHETA1 | c.195C>A p.G65= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100825319; called by muse, mutect2, varscan2
- SNAPC4 | c.4164C>A p.T1388= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV100046936; called by muse, mutect2, varscan2
